Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72M, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72M-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-3

Carcinoma renal cell
chromophobe 8317/3

Site L Kidney NOS
C64.9

QW8/9/13

Diagnosis:

Kidney, left, robotic partial nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe type, eosinophilic variant. This diagnosis is supported by immunostains which show the following results:

CK7: focally positive

Vimentin: negative

CD15: negative

Sarcomatoid features: Not identified

Histologic grade (if applicable): 2

Tumor size (greatest dimension): 3.5 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not identified

Gerota's fascia: Not identified

Renal sinus: Not present in specimen

Major veins (renal vein or segmental branches, IVC): Not present in specimen

Ureter: Not present in specimen

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Free of tumor

Renal capsular margin (partial nephrectomy only): Free of tumor

Paranephric adipose tissue margin (partial nephrectomy only): Free of tumor

Adrenal gland: Not present in specimen

Lymph nodes: None submitted

Other significant findings: None

[page 2 of 3]
AJCC Staging:

pT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old male with left renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: robotic partial nephrectomy

Side of specimen: left

Size and weight of specimen: 4.5 x 4.5 x 4.0 cm, 36 grams

Orientation: Perinephric fat=blue, parenchymal margin=black

Presence/absence of adrenal gland: absent

Tumor site: cortex

Tumor description: well circumscribed, smooth, pink/tan and rubbery with a central stellate gray/white fibrosis.

Tumor size: 3.5 x 3.4 x 3.2 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: the mass is confined to the kidney, bulges the capsule

Extent of invasion:

Perirenal adipose tissue: does not involve

Gerota' s fascia: does not involve

Renal vein: n/a

[page 3 of 3]
Ureter: n/a

Renal Sinus: n/a

Pelvic/Caliceal: n/a

Adrenal: n/a

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: negative 0.2 cm from the perirenal adipose tissue margin

Renal vein: n/a

Renal artery: n/a

Ureter: n/a

Parenchymal margin: mass grossly abuts the parenchymal margin

Description of kidney away from tumor: red/brown and smooth

Hilar lymph nodes: n/a

Other significant findings: none

Tissue submitted for : Tumor given to

Digital picture: no

Block summary:

A1,A2 - perpendicular of mass abutting the parenchymal margin

A3,A4 - mass abutting the capsule with overlying perinephric fat

hw 7/30/13

DATE 7/26/13

Source: NCI Genomic Data Commons file 459a549c-5a56-4189-9cef-6ef3fe08d20b (TCGA-UW-A72M.0394D68B-20D1-4765-9993-2AF8A8572CAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).